Gene-level copy-number profile of tumor specimen HTMCP-03-06-02217-01A from CGCI case HTMCP-03-06-02217, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 45.9 years (16,767 days).
Specimen HTMCP-03-06-02217-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 168cd485-ce5d-4597-9e29-b09d918b6aa1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02217-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/1725ecc1-93ec-48d9-be7a-600e67f35eab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 3; copy number 2: 8,118; copy number 3: 26,243; copy number 4: 14,341; copy number 5: 5,947; copy number 6: 3,255; copy number 7: 396; copy number 8: 4; copy number 11: 47.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,692,032–19,131,167, 16 genes (within-gene range 0–5): RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3.
- chr14:20,891,399–20,936,255, 4 genes: RNASE3, AL355922.4, AL355922.3, AL355922.1.
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–4): ACOT1, NT5CP2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 447 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:86,235,321–86,267,424, 2 genes, copy number 8: RNU6-1129P, AC108733.1.
- chr3:197,634,315–197,646,017, 2 genes, copy number 8: AC024560.2, AC024560.3.
- chr8:127,289,817–127,482,139, 4 genes, copy number 7: CASC8, AC018714.1, POU5F1B, CCAT2.
- chr13:87,423,493–114,337,626, 365 genes, copy number 7 (broad region; genes not listed).
- chr14:21,887,857–22,494,883, 73 genes, copy number 7–11 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 11: TRAC.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
